Somatic mutation profile of tumor specimen C3N-00246-01 (aliquot CPT0025580010) from CPTAC case C3N-00246, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 44.5 years (16,268 days).
Specimen C3N-00246-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bd1ce8a-3639-4ec2-9a68-78594e9907aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00246-32 (Blood Derived Normal), aliquot CPT0028450002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df6e4ed4-254c-4d82-8ab1-73093ad94c5c

The open-access MAF lists 46 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 9, Intron 4, In Frame Del 2, Nonsense Mutation 2, 3'UTR 1, Frame Shift Del 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLDN17 | c.520G>C p.V174L | Missense Mutation (SNP) | VAF 134/357 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.166); catalogued as rs148072252; called by muse, mutect2, varscan2
- FAM153B | c.332C>T p.A111V (on ENST00000253490; = p.A34V on NM_001265615.1) | Missense Mutation (SNP) | VAF 110/548 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.695); catalogued as rs376884721; called by muse, mutect2, varscan2
- KDM5C | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 183/301 reads (61%) | catalogued as COSV62890827; called by muse, mutect2, varscan2
- NKAPL | c.1100G>A p.R367K | Missense Mutation (SNP) | VAF 61/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59199017; called by muse, mutect2, varscan2
- NLRP5 | c.1656G>A p.M552I | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs761012006, COSV66765236, COSV66767256; called by muse, mutect2
- OR52N2 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs746188141, COSV57676062, COSV57677371; called by muse, mutect2
- SLC9B1 | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.019); catalogued as rs766680278; called by muse, mutect2, varscan2
- STAT3 | c.1387_1389del p.V463del | In Frame Del (DEL) | VAF 41/143 reads (29%) | catalogued as rs113994138; called by pindel, varscan2
- TXNIP | c.886A>G p.I296V | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs781865277; called by muse, mutect2, varscan2
- ADNP2 | c.1784C>A p.S595* | Nonsense Mutation (SNP) | VAF 74/197 reads (38%) | called by muse, mutect2, varscan2
- CDH4 | c.1122C>A p.N374K | Missense Mutation (SNP) | VAF 103/145 reads (71%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- CHD1 | c.3316G>T p.G1106W | Missense Mutation (SNP) | VAF 114/233 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- CYP2S1 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 61/208 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- DDX18 | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DUS3L | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 123/334 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- FSCB | c.245A>G p.K82R | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); called by muse, mutect2
- IRGM | c.109A>G p.T37A | Missense Mutation (SNP) | VAF 93/364 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMT2C | c.673T>G p.W225G | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LIG4 | c.410G>T p.C137F | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- MELTF | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- MTPAP | c.292T>A p.F98I | Missense Mutation (SNP) | VAF 96/246 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- MYO15A | c.7544G>T p.R2515L | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- MYO1D | c.2367C>G p.I789M | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- PP2D1 | c.1232A>T p.E411V | Missense Mutation (SNP) | VAF 78/137 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RYR3 | c.13852G>C p.D4618H (on ENST00000389232; = p.D4619H on NM_001036.6) | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNURF | c.56C>A p.P19Q | Missense Mutation (SNP) | VAF 180/514 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by mutect2, varscan2
- TTN | c.100748C>G p.T33583S (on ENST00000591111; = p.T26159S on NM_003319.4) | Missense Mutation (SNP) | VAF 71/183 reads (39%) | PolyPhen benign (0.022); called by muse, mutect2, varscan2
- VHL | c.479_480del p.E160Afs*13 | Frame Shift Del (DEL) | VAF 136/286 reads (48%) | called by pindel, varscan2
- ZNF331 | c.521T>C p.L174P | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF521 | c.505_522del p.T169_Y174del | In Frame Del (DEL) | VAF 62/323 reads (19%) | called by mutect2, pindel, varscan2
- CSKMT | c.246G>A p.V82= | Silent (SNP) | VAF 86/219 reads (39%) | called by muse, mutect2, varscan2
- DVL3 | c.1695C>T p.A565= | Silent (SNP) | VAF 64/194 reads (33%) | catalogued as rs1241094306; called by muse, mutect2, varscan2
- DYM | c.567C>T p.H189= | Silent (SNP) | VAF 90/301 reads (30%) | called by muse, mutect2, varscan2
- FANCC | c.474G>A p.A158= | Silent (SNP) | VAF 126/328 reads (38%) | catalogued as rs768342908; ClinVar: likely benign; called by muse, mutect2, varscan2
- FURIN | c.411C>T p.A137= | Silent (SNP) | VAF 56/176 reads (32%) | catalogued as rs146069392; called by muse, mutect2, varscan2
- NEFM | c.1056C>T p.H352= | Silent (SNP) | VAF 85/239 reads (36%) | called by muse, mutect2, varscan2
- PARD6B | c.198T>C p.H66= | Silent (SNP) | VAF 97/137 reads (71%) | called by muse, mutect2, varscan2
- SHANK1 | c.6126G>T p.G2042= | Silent (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- TNRC18 | c.1497G>C p.G499= | Silent (SNP) | VAF 189/340 reads (56%) | called by muse, mutect2, varscan2
- AAK1 | c.*14146G>A | 3'UTR (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- ACBD5 | chr10:27195660 T>A | 3'Flank (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- ITGA3 | c.1537+27G>C | Intron (SNP) | VAF 86/227 reads (38%) | called by muse, mutect2, varscan2
- NAV3 | c.2024-12975C>A | Intron (SNP) | VAF 61/178 reads (34%) | called by muse, mutect2, varscan2
- NOL8 | c.282-796_282-789del | Intron (DEL) | VAF 46/181 reads (25%) | called by mutect2, pindel, varscan2
- PJVK | c.212-34A>C | Intron (SNP) | VAF 51/103 reads (50%) | called by muse, mutect2, varscan2
- RRN3P1 | n.2962T>G | RNA (SNP) | VAF 44/160 reads (28%) | called by mutect2, varscan2
